CCDI case PBCBKF — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Vagina.
https://portal.gdc.cancer.gov/cases/913dc494-fee1-4071-8700-af14a2704986

Demographics
Sex at birth: female; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Clear cell adenocarcinoma, NOS: ICD-O-3 morphology code: 8310/3; Tissue or organ of origin: Vagina, NOS; Age at diagnosis: 17.3 years (6,331 days).

Biospecimens (2 samples)
- Sample 0DNRTO: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DNRUS: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
